Somatic mutation profile of tumor specimen 0D9CNE from CCDI case PBBHWP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 13.4 years (4,912 days).
Specimen 0D9CNE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e635c324-74db-4f93-b285-d5b57e5193de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9CNQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b60bd6fb-c4a2-4f60-9dbd-4920d979f11b

The open-access MAF lists 26 somatic variants for this specimen: 16 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 9, Nonsense Mutation 2, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 122/574 reads (21%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 137/1072 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASTL | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 68/556 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs139129570, COSV60905222; called by muse, mutect2
- ATRX | c.2422C>T p.R808* | Nonsense Mutation (SNP) | VAF 155/352 reads (44%) | catalogued as COSV64874953; called by muse, mutect2, varscan2
- C3 | c.2071C>T p.R691C | Missense Mutation (SNP) | VAF 83/376 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55579741; called by muse, mutect2, varscan2
- FBRSL1 | c.2030G>A p.G677D | Missense Mutation (SNP) | VAF 47/482 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV55513912; called by muse, mutect2
- IL16 | c.2290G>A p.A764T (on ENST00000302987 / NM_172217.5; = p.A63T on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/461 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs757579432, COSV57263028; called by muse, mutect2
- KCTD13 | c.286A>G p.I96V | Missense Mutation (SNP) | VAF 93/500 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.58); catalogued as rs369680799; called by muse, mutect2, varscan2
- SH3PXD2A | c.2788G>A p.E930K (on ENST00000369774 / NM_001365079.1; = p.E902K on NM_014631.2) | Missense Mutation (SNP) | VAF 34/544 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs778304934, COSV60116450; called by muse, mutect2
- TP53 | c.472del p.R158Afs*12 | Frame Shift Del (DEL) | VAF 266/442 reads (60%) | catalogued as CM004341, CM121763, COSV52677865, COSV52699654, COSV52778687; called by mutect2, varscan2
- ADAM2 | c.1970A>T p.D657V | Missense Mutation (SNP) | VAF 42/842 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- CNTRL | c.5188C>T p.Q1730* | Nonsense Mutation (SNP) | VAF 56/812 reads (7%) | called by muse, mutect2
- GORAB | c.949A>G p.S317G | Missense Mutation (SNP) | VAF 44/892 reads (5%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); called by muse, mutect2
- HCN1 | c.1654A>T p.S552C | Missense Mutation (SNP) | VAF 180/733 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SCML1 | c.276C>G p.F92L (on ENST00000380041 / NM_001037540.3; = p.F65L on NM_006746.6) | Missense Mutation (SNP) | VAF 167/334 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STX19 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 231/567 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- AHNAK2 | c.7830T>C p.S2610= | Silent (SNP) | VAF 26/138 reads (19%) | called by muse, mutect2
- ARHGAP36 | c.699A>G p.K233= | Silent (SNP) | VAF 18/468 reads (4%) | catalogued as COSV52264544; called by muse, mutect2
- EPB41L4A | c.801C>T p.N267= | Silent (SNP) | VAF 70/852 reads (8%) | catalogued as rs771415842, COSV54873342; called by muse, mutect2
- IPO5 | c.399G>A p.L133= | Silent (SNP) | VAF 46/710 reads (6%) | called by muse, mutect2
- KDR | c.2382A>G p.G794= | Silent (SNP) | VAF 35/299 reads (12%) | called by muse, mutect2, varscan2
- OR56A5 | c.90G>A p.L30= | Silent (SNP) | VAF 21/498 reads (4%) | called by muse, mutect2
- OR5I1 | c.768T>C p.T256= | Silent (SNP) | VAF 28/890 reads (3%) | catalogued as rs926405212; called by muse, mutect2
- PLA2G7 | c.576C>T p.D192= | Silent (SNP) | VAF 228/867 reads (26%) | called by muse, mutect2, varscan2
- VAMP7 | c.609C>T p.I203= | Silent (SNP) | VAF 116/723 reads (16%) | catalogued as COSV52901402; called by muse, mutect2, varscan2
- KIR2DL1 | c.-27C>T | 5'UTR (SNP) | VAF 91/374 reads (24%) | catalogued as rs201795960; called by muse, mutect2, varscan2
